Somatic mutation profile of tumor specimen MMRF_1038_1_BM_CD138pos (aliquot MMRF_1038_1_BM_CD138pos_T2_TSE61_K02459) from MMRF case MMRF_1038, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.1 years (25,255 days).
Specimen MMRF_1038_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 223c9cb2-745b-455f-9e7a-20448dbaa4e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1038_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1038_1_PB_Whole_C1_TSE61_K02452; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b55ac26e-f167-46ca-8a17-f00a6faa3b5a

The open-access MAF lists 104 somatic variants for this specimen: 49 protein-altering or splice-affecting, 9 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 29, Silent 9, 5'UTR 8, Intron 3, 5'Flank 3, Nonsense Mutation 2, RNA 1, IGR 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.2521C>T p.Q841* | Nonsense Mutation (SNP) | VAF 69/144 reads (48%) | catalogued as rs1555154946; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/82 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD50 | c.2207A>G p.D736G | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs754011039; called by muse, mutect2, varscan2
- ARHGEF4 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV58117961; called by muse, mutect2, varscan2
- CCDC68 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs1319352788; called by muse, mutect2, varscan2
- CHRNA7 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.452); catalogued as rs780262851, COSV60967908; called by mutect2, varscan2
- CMYA5 | c.11637C>G p.I3879M | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as rs1165995076; called by muse, mutect2, varscan2
- DIAPH2 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV61289727; called by muse, mutect2
- FKRP | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.737); catalogued as rs1037585549; called by muse, mutect2, varscan2
- GPC5 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs145336505; called by muse, mutect2, varscan2
- KALRN | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768341806, COSV53755646; called by muse, mutect2, varscan2
- LZTS3 | c.1642G>A p.G548R (on ENST00000329152; = p.G502R on NM_001282533.2) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs759625241; called by muse, varscan2
- MORN5 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as rs775254747, COSV65649041; called by muse, mutect2, varscan2
- PTH1R | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 98/160 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs768504854, COSV100481190; called by muse, mutect2, varscan2
- PUS7 | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs769099069; called by muse, mutect2, varscan2
- RBM18 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 5/115 reads (4%) | catalogued as rs1312371590; called by muse, mutect2
- SLC35F6 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs772057516, COSV60426417; called by muse, mutect2, varscan2
- SYNE1 | c.4093C>T p.R1365C (on ENST00000367255 / NM_182961.4; = p.R1372C on NM_033071.3) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770015858, COSV54954982; called by muse, mutect2, varscan2
- TJP1 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 102/140 reads (73%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV62042446; called by muse, mutect2, varscan2
- TMEM200A | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422589435, COSV51649187; called by muse, mutect2, varscan2
- TRMT6 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs769987469; called by muse, mutect2, varscan2
- WLS | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.202); catalogued as rs754260821; called by muse, mutect2, varscan2
- ZNF599 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs146342141; called by muse, mutect2, varscan2
- ADAM9 | c.2051G>T p.S684I | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP4 | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 66/66 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ANKRD54 | c.393A>C p.E131D | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD55 | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- APOB | c.12416G>T p.G4139V | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- APOB | c.12415G>A p.G4139R | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC141 | c.2980G>C p.V994L | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CELSR1 | c.7218_7226del p.T2407_P2409del | In Frame Del (DEL) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- CHD8 | c.1106C>T p.S369F (on ENST00000646647 / NM_001170629.2; = p.S90F on NM_020920.4) | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DIS3L | c.2537C>A p.A846E (on ENST00000319212 / NM_001143688.3; = p.A763E on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DSG2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DSG3 | c.1409A>G p.D470G | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- EPS8L1 | c.494G>T p.R165L (on ENST00000201647 / NM_133180.3; = p.R38L on NM_017729.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GFPT1 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- GLRA1 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPATCH8 | c.3937A>G p.T1313A | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- H4C2 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- LVRN | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM | c.1989G>T p.L663F | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NCOR1 | c.936T>G p.D312E | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PPP2R1A | c.1001T>G p.V334G | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRPF4B | c.2502T>G p.D834E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SIAH3 | c.168_175del p.S56Rfs*74 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- SLC7A11 | c.438dup p.G147Wfs*13 | Frame Shift Ins (INS) | VAF 41/89 reads (46%) | called by mutect2, pindel, varscan2
- VNN1 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP2 | c.1288G>A p.D430N (on ENST00000628543; = p.D605N on NM_152381.6) | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EPHA7 | c.381T>C p.Y127= | Silent (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- GREB1 | c.4674C>T p.L1558= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs757789807; called by muse, mutect2, varscan2
- PDZD4 | c.351G>A p.P117= | Silent (SNP) | VAF 35/36 reads (97%) | catalogued as rs781966669, COSV51252535; called by muse, mutect2, varscan2
- RASGRP2 | c.1558C>T p.L520= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV62449628; called by muse, mutect2, varscan2
- SLC45A3 | c.55T>C p.L19= | Silent (SNP) | VAF 40/72 reads (56%) | called by muse, mutect2, varscan2
- TDRD6 | c.4722T>C p.C1574= | Silent (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- TKTL2 | c.1509C>A p.V503= | Silent (SNP) | VAF 130/263 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.39102T>A p.I13034= (on ENST00000591111; = p.I5610= on NM_003319.4) | Silent (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
- UBQLN3 | c.1239G>A p.L413= | Silent (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- ADGRB1 | c.*276C>T | 3'UTR (SNP) | VAF 26/38 reads (68%) | catalogued as rs931013972; called by muse, mutect2, varscan2
- ALKBH8 | chr11:107503338 T>C | 3'Flank (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- AP000944.2 | chr11:65423100 C>G | 5'Flank (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- B4GALT6 | c.*604C>G | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- BEND4 | c.*3735G>A | 3'UTR (SNP) | VAF 49/101 reads (49%) | called by muse, mutect2, varscan2
- BRINP1 | c.-194G>A | 5'UTR (SNP) | VAF 26/104 reads (25%) | catalogued as rs1241395800; called by muse, mutect2, varscan2
- CAV2 | c.*1621C>G | 3'UTR (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- CD80 | c.*509T>C | 3'UTR (SNP) | VAF 84/128 reads (66%) | called by muse, mutect2, varscan2
- CDH2 | c.*1014C>A | 3'UTR (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- DBT | c.*4669C>T | 3'UTR (SNP) | VAF 27/57 reads (47%) | catalogued as rs1473989494; called by muse, mutect2, varscan2
- EEF1D | c.-515C>G | 5'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- EMBP1 | n.2529T>A | RNA (SNP) | VAF 94/194 reads (48%) | called by muse, varscan2
- FCAR | c.*368G>A | 3'UTR (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- FNDC5 | c.*1697G>A | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- GJA1 | c.*936T>C | 3'UTR (SNP) | VAF 64/150 reads (43%) | called by muse, mutect2, varscan2
- HDGFL3 | c.*157T>C | 3'UTR (SNP) | VAF 56/239 reads (23%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.*469T>C | 3'UTR (SNP) | VAF 35/116 reads (30%) | catalogued as rs1028316808; called by muse, mutect2, varscan2
- IGFALS | c.*129G>A | 3'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- LARGE2 | c.*147A>G | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- LIMS2 | c.*343G>A | 3'UTR (SNP) | VAF 36/59 reads (61%) | catalogued as rs1440140283; called by muse, mutect2, varscan2
- LRRIQ3 | c.*453_*457del | 3'UTR (DEL) | VAF 74/169 reads (44%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.*80C>G | 3'UTR (SNP) | VAF 47/83 reads (57%) | catalogued as rs961205360; called by muse, mutect2, varscan2
- MED4 | c.-7G>A | 5'UTR (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- MGAT2 | c.-171G>C | 5'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- MKLN1 | c.*3272A>T | 3'UTR (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- MLLT10 | c.*660G>A | 3'UTR (SNP) | VAF 17/48 reads (35%) | catalogued as rs1024930342; called by muse, mutect2, varscan2
- MYO1E | c.-55C>T | 5'UTR (SNP) | VAF 33/134 reads (25%) | catalogued as COSV99893901; called by muse, mutect2, varscan2
- NLGN4Y | chrY:14522895 T>G | 5'Flank (SNP) | VAF 46/47 reads (98%) | called by muse, mutect2, varscan2
- NUP98 | c.*483del | 3'UTR (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- PCDH11X | c.3033+498C>A | Intron (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- PDE1A | c.*502G>A | 3'UTR (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- POFUT2 | c.1136+432C>T | Intron (SNP) | VAF 82/173 reads (47%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+2087G>T | Intron (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- RHEB | c.-323T>G | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs992590062; called by muse, mutect2, varscan2
- SEC16A | c.*958C>T | 3'UTR (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- SGTB | c.*3338C>T | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- SH3BP4 | c.*344G>A | 3'UTR (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- STXBP1 | c.*901G>T | 3'UTR (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- TMEM182 | c.*904C>G | 3'UTR (SNP) | VAF 65/139 reads (47%) | catalogued as rs777062498; called by muse, mutect2, varscan2
- TNS3 | c.*415C>T | 3'UTR (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- TPO | c.-12G>T | 5'UTR (SNP) | VAF 46/93 reads (49%) | called by muse, mutect2, varscan2
- TRIB1 | c.*1452C>A | 3'UTR (SNP) | VAF 59/105 reads (56%) | called by muse, mutect2, varscan2
- UBLCP1 | c.*536T>C | 3'UTR (SNP) | VAF 120/173 reads (69%) | called by muse, varscan2
- Unknown | chr3:132873742 del C | IGR (DEL) | VAF 52/159 reads (33%) | called by mutect2, pindel, varscan2
- VEGFA | chr6:43770440 C>T | 5'Flank (SNP) | VAF 19/84 reads (23%) | catalogued as rs945528690; called by muse, mutect2, varscan2
- ZC3HAV1 | c.-348del | 5'UTR (DEL) | VAF 35/81 reads (43%) | called by mutect2, pindel, varscan2
